Gene-level copy-number profile of tumor specimen ALCH-B55L-TTP1-A from ALCHEMIST case ALCH-B55L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,224 days).
Specimen ALCH-B55L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f76c5a62-7eb4-4373-a465-f6c0f8794436.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B55L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/ca641435-f94e-4c44-8af2-6de3fd25e03a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 18,170; copy number 2: 37,997; copy number 3: 2,043; copy number 4: 76; copy number 6: 1; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr7:66,493,607–66,592,397, 5 genes (within-gene range 0–2): GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr8:12,333,644–12,359,391, 3 genes: RNA5SP254, DEFB108E, ZNF705CP.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:101,686,547–101,689,093, 1 gene (within-gene range 0–2): AP000426.1.
- chr9:34,521,043–34,681,981, 16 genes: ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2.
- chr9:132,161,676–132,244,526, 1 gene: NTNG2.
- chr9:132,582,606–132,590,252, 1 gene: BARHL1.
- chr11:32,435,738–32,440,383, 6 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr12:122,167,738–122,203,471, 2 genes: LRRC43, IL31.
- chr14:104,769,349–104,795,751, 2 genes: AL583722.1, AKT1.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:75,192,465–75,286,800, 7 genes: AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P.
- chr17:66,964,707–67,033,398, 3 genes (within-gene range 0–2): CACNG4, AC005544.1, AC005544.2.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–1): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.
- chr19:39,125,770–39,182,816, 2 genes: PAK4, AC011443.1.
- chr20:50,794,894–50,882,676, 2 genes: BCAS4, TMSB4XP6.
- chr22:29,436,534–29,581,327, 7 genes (within-gene range 0–1): RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1.
- chr22:29,608,900–29,770,413, 8 genes (within-gene range 0–2): RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10.
- chr22:41,064,052–41,075,239, 3 genes: AL080243.2, Y_RNA, AL080243.1.
- chr22:41,174,591–41,589,871, 18 genes (within-gene range 0–3): EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A, POLR3H, AL023553.1, CSDC2, PMM1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,936,581–248,937,043, 1 gene, copy number 7: RPL23AP25.
- chr16:2,339,150–2,426,699, 1 gene, copy number 6 (within-gene range 2–6): ABCA17P.

Autosomal genes at a single copy (total copy number 1): 15,849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
